Somatic mutation profile of tumor specimen MMRF_1851_1_BM_CD138pos (aliquot MMRF_1851_1_BM_CD138pos_T1_KBS5U_L07287) from MMRF case MMRF_1851, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.2 years (23,097 days).
Specimen MMRF_1851_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63ae9fa3-8017-471b-9bcf-adf8b8817404.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1851_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1851_1_PB_CD3pos_C5_KBS5U_L07294; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ff1e2e6-010c-402d-aa64-fe70a99021b5

The open-access MAF lists 88 somatic variants for this specimen: 41 protein-altering or splice-affecting, 10 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, 3'UTR 24, Silent 10, Intron 8, Frame Shift Del 2, Splice Site 2, 3'Flank 2, 5'UTR 2, In Frame Ins 1, Nonsense Mutation 1, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BACH2 | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 94/94 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as rs1227106751; called by muse, mutect2, varscan2
- C11orf95 | c.1832C>T p.T611M | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1565057982; called by muse, mutect2, varscan2
- DIS3 | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 53/53 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66706787; called by muse, mutect2, varscan2
- FANCA | c.2267G>A p.R756H | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs137913973, COSV66881343; called by muse, mutect2, varscan2
- GANAB | c.1310G>A p.R437Q | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs1472158539, COSV100648258; called by muse, mutect2, varscan2
- IGHJ6 | c.58T>C p.S20P | Missense Mutation (SNP) | VAF 27/31 reads (87%) | PolyPhen probably damaging (0.96); catalogued as rs368997749; called by muse, mutect2, varscan2
- INSR | c.2296G>A p.D766N | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs774340801, COSV57168630; called by muse, mutect2, varscan2
- IZUMO1R | c.335C>T p.P112L (on ENST00000440961; = p.P119L on NM_001199206.3) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs202165897; called by muse, varscan2
- KNDC1 | c.2693G>A p.R898H | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs1462152347, COSV100465949; called by muse, mutect2, varscan2
- M1AP | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.26); PolyPhen probably damaging (1); catalogued as COSV99303736; called by muse, mutect2, varscan2
- MUC16 | c.3908C>G p.S1303C | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as COSV67498168; called by muse, mutect2, varscan2
- PTPRF | c.2836G>A p.G946R | Missense Mutation (SNP) | VAF 101/165 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1439775308; called by muse, mutect2, varscan2
- RAB38 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 157/369 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs761810753, COSV54713351, COSV54714768; called by muse, mutect2, varscan2
- TBX18 | c.1045C>T p.R349* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as rs1384411524, COSV100858519; called by muse, mutect2, varscan2
- ADAM15 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CATSPER4 | c.437A>G p.N146S | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- CES1 | c.905A>C p.K302T | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- CHD2 | c.2284dup p.C762Lfs*8 | Frame Shift Ins (INS) | VAF 50/142 reads (35%) | called by mutect2, pindel, varscan2
- DCD | c.121C>A p.Q41K | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH8 | c.9874G>T p.A3292S | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- EML4 | c.1109A>G p.D370G | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- EXO1 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 80/161 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HECTD4 | c.6560T>G p.I2187S | Missense Mutation (SNP) | VAF 66/141 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGHV2-70 | c.265_290del p.T89Pfs*? | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | called by mutect2, varscan2
- IGHV2-70D | c.109C>A p.L37I | Missense Mutation (SNP) | VAF 34/35 reads (97%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- KLHL30 | c.177_178del p.A60Hfs*5 | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | called by mutect2, varscan2
- KRTAP4-16 | c.466C>A p.P156T | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MTRF1L | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 8/8 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MYBL2 | c.470G>T p.W157L | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOP14 | c.107T>G p.V36G | Missense Mutation (SNP) | VAF 80/173 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- NPR2 | c.3005C>T p.S1002F | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PEX6 | c.1479+1G>A p.X493_splice | Splice Site (SNP) | VAF 30/69 reads (43%) | called by muse, mutect2, varscan2
- PHC3 | c.51_53dup p.S18dup (on ENST00000494943 / NM_001308116.2; = p.S30dup on NM_024947.4) | In Frame Ins (INS) | VAF 49/123 reads (40%) | called by mutect2, pindel, varscan2
- QPCTL | c.73C>A p.P25T | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RPS6KA6 | c.1365+2T>C p.X455_splice | Splice Site (SNP) | VAF 62/65 reads (95%) | called by muse, mutect2, varscan2
- SNX16 | c.819A>C p.R273S | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SOAT2 | c.1561C>T p.H521Y | Missense Mutation (SNP) | VAF 90/183 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SOGA3 | c.2356G>T p.V786L | Missense Mutation (SNP) | VAF 44/49 reads (90%) | SIFT tolerated (0.15); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TOPAZ1 | c.2270G>A p.S757N | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF417 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZNFX1 | c.1725G>C p.E575D | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- AXIN1 | c.2130G>A p.A710= | Silent (SNP) | VAF 12/17 reads (71%) | catalogued as rs749294095; called by muse, mutect2, varscan2
- CR1L | c.82C>T p.L28= | Silent (SNP) | VAF 41/76 reads (54%) | called by muse, mutect2, varscan2
- ECRG4 | c.66G>A p.L22= | Silent (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- HERC1 | c.12420T>A p.S4140= | Silent (SNP) | VAF 48/102 reads (47%) | called by muse, varscan2
- JADE3 | c.1026C>T p.H342= | Silent (SNP) | VAF 18/18 reads (100%) | catalogued as rs1311939874; called by muse, mutect2, varscan2
- MGAM2 | c.826C>T p.L276= | Silent (SNP) | VAF 49/115 reads (43%) | catalogued as rs267601329; called by muse, mutect2, varscan2
- MYH2 | c.5319G>A p.E1773= | Silent (SNP) | VAF 45/102 reads (44%) | catalogued as COSV55447999; called by muse, mutect2, varscan2
- PTPRU | c.2880C>T p.A960= | Silent (SNP) | VAF 48/101 reads (48%) | called by muse, mutect2, varscan2
- SDK1 | c.1065G>A p.A355= | Silent (SNP) | VAF 36/81 reads (44%) | catalogued as rs769886680, COSV67361051, COSV67369890; called by muse, mutect2, varscan2
- SZT2 | c.6108C>T p.F2036= (on ENST00000634258 / NM_001365999.1; = p.F1979= on NM_015284.4) | Silent (SNP) | VAF 47/89 reads (53%) | called by muse, mutect2, varscan2
- C2CD2 | c.*897G>A | 3'UTR (SNP) | VAF 39/69 reads (57%) | called by muse, mutect2, varscan2
- CAPN7 | c.*355T>C | 3'UTR (SNP) | VAF 35/62 reads (56%) | called by muse, mutect2, varscan2
- CD8B2 | c.620+2848C>G | Intron (SNP) | VAF 86/198 reads (43%) | called by muse, mutect2, varscan2
- CEMIP2 | c.3194+51T>A | Intron (SNP) | VAF 20/37 reads (54%) | called by muse, mutect2, varscan2
- COL21A1 | c.2091+138A>G | Intron (SNP) | VAF 10/16 reads (63%) | called by muse, mutect2, varscan2
- DYNC2LI1 | c.321-1229C>T | Intron (SNP) | VAF 17/33 reads (52%) | called by muse, mutect2, varscan2
- FAM135B | c.*344A>G | 3'UTR (SNP) | VAF 46/67 reads (69%) | catalogued as rs1197522551; called by muse, mutect2, varscan2
- FAM83G | chr17:18969469 C>T | 3'Flank (SNP) | VAF 3/48 reads (6%) | catalogued as rs1382428491; called by muse, mutect2
- GFRA1 | c.*547A>G | 3'UTR (SNP) | VAF 25/50 reads (50%) | catalogued as rs944479638; called by muse, mutect2, varscan2
- GLI2 | c.*952G>A | 3'UTR (SNP) | VAF 54/121 reads (45%) | catalogued as rs914764088; called by muse, mutect2, varscan2
- GSTCD | c.1240+32009C>T | Intron (SNP) | VAF 7/104 reads (7%) | catalogued as rs1442780331; called by muse, mutect2
- HMX3 | c.*406T>G | 3'UTR (SNP) | VAF 19/28 reads (68%) | called by muse, mutect2, varscan2
- KCNT1 | chr9:135793094 C>T | 3'Flank (SNP) | VAF 4/60 reads (7%) | catalogued as rs1028938727; called by muse, mutect2
- KIF20B | c.*763A>T | 3'UTR (SNP) | VAF 94/212 reads (44%) | called by muse, mutect2, varscan2
- KLHL36 | c.*1327_*1330dup | 3'UTR (INS) | VAF 21/49 reads (43%) | called by mutect2, pindel, varscan2
- MAP3K13 | c.*414C>G | 3'UTR (SNP) | VAF 28/74 reads (38%) | called by muse, mutect2, varscan2
- MTA1 | c.190+205T>C | Intron (SNP) | VAF 65/102 reads (64%) | called by muse, mutect2, varscan2
- NOS1 | c.*1353del | 3'UTR (DEL) | VAF 8/79 reads (10%) | called by mutect2, pindel
- PCDHB4 | c.*542C>G | 3'UTR (SNP) | VAF 25/48 reads (52%) | called by muse, mutect2, varscan2
- PCSK7 | c.*2C>G | 3'UTR (SNP) | VAF 23/52 reads (44%) | called by muse, mutect2, varscan2
- PDK3 | c.*727G>C | 3'UTR (SNP) | VAF 8/8 reads (100%) | called by muse, mutect2
- PHF24 | c.*764T>A | 3'UTR (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- PRKCG | c.-177C>G | 5'UTR (SNP) | VAF 75/139 reads (54%) | called by muse, mutect2, varscan2
- RAB17 | c.435+569C>T | Intron (SNP) | VAF 30/63 reads (48%) | catalogued as rs149153125; called by muse, mutect2, varscan2
- RBM33 | c.*4181T>G | 3'UTR (SNP) | VAF 14/32 reads (44%) | catalogued as rs1034338301; called by muse, varscan2
- SESN3 | c.*3842G>C | 3'UTR (SNP) | VAF 33/60 reads (55%) | catalogued as rs908104148; called by muse, mutect2, varscan2
- SIAH3 | c.*1776T>C | 3'UTR (SNP) | VAF 3/18 reads (17%) | called by muse, varscan2
- SIX1 | c.-245A>G | 5'UTR (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- SLC16A2 | c.*2122G>A | 3'UTR (SNP) | VAF 20/20 reads (100%) | called by muse, mutect2, varscan2
- SLC6A17 | c.*1575G>A | 3'UTR (SNP) | VAF 27/60 reads (45%) | called by muse, mutect2, varscan2
- SPA17 | c.*538G>A | 3'UTR (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2
- SPRED1 | c.*2870C>A | 3'UTR (SNP) | VAF 33/69 reads (48%) | called by muse, mutect2, varscan2
- SYT9 | c.*606A>T | 3'UTR (SNP) | VAF 38/78 reads (49%) | called by muse, mutect2, varscan2
- TMEM33 | c.*3048A>G | 3'UTR (SNP) | VAF 19/36 reads (53%) | called by muse, mutect2, varscan2
- TMOD2 | c.*823T>C | 3'UTR (SNP) | VAF 32/59 reads (54%) | called by muse, mutect2, varscan2
- TRAPPC11 | c.2852-33T>C | Intron (SNP) | VAF 12/21 reads (57%) | called by muse, mutect2, varscan2
- ZNF720P1 | n.148A>T | RNA (SNP) | VAF 40/86 reads (47%) | called by muse, mutect2, varscan2
